Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A053, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A053-01A (Primary Tumor).

[page 1 of 2]
adenocarcinoma, endometrioid, NOS 8380/3
Site: endometrium C54.1 w 5/2/11

- 1: SP: Right tube and ovary (fs)
- 2: SP: Uterus, cervix, left tube and ovary
- 3: SP: Right external iliac lymph nodes
- 4: SP: Right obturator lymph nodes
- 5: SP: Right hypogastric lymph nodes
- 6: SP: Left common iliac lymph nodes
- 7: SP: Left external iliac lymph nodes
- 8: SP: Left obturator lymph nodes
- 9: SP: Left hypogastric lymph nodes
- 10: SP: Left para-aortic lymph nodes
- 11: SP: Right para-aortic lymph nodes

- 1) OVARY AND FALLOPIAN TUBE, RIGHT; SALPINGO-OOPHORECTOMY:
- BENIGN SEROUS CYSTADENOMA.
- UNREMARKABLE FALLOPIAN TUBE.
- 2) UTERUS, LEFT FALLOPIAN TUBE AND OVARY; TOTAL ABDOMINAL HYSTERECTOMY AND SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, FIGO GRADE III (> 50% SOLID GROWTH), NUCLEAR GRADE 3.
- THE TUMOR INVADERS TO <= HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 4 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 16 MM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- NO VASCULAR INVASION IS IDENTIFIED.
- THE ENDOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: CYSTIC ATROPHY.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: LEIOMYOMAS.
- THE LEFT FALLOPIAN TUBE AND OVARY, AND PORTION OF RIGHT FALLOPIAN TUBE ARE NEGATIVE FOR TUMOR.
- 3) LYMPH NODES, RIGHT EXTERNAL ILIAC; BIOPSY:
- TWO BENIGN LYMPH NODES (0/2).

HA ONE m.
prior to a
ok - get OMF...

hwy 5/2/11

[page 2 of 2]
- 4) LYMPH NODE, RIGHT OBTURATOR; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 5) LYMPH NODE, RIGHT HYPOGASTRIC; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 6) LYMPH NODE, LEFT COMMON ILIAC; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 7) LYMPH NODES, LEFT EXTERNAL ILIAC; BIOPSY:
- FOUR BENIGN LYMPH NODES (0/4).
- 8) LYMPH NODE, LEFT OBTURATOR; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 9) LYMPH NODES, LEFT HYPOGASTRIC; BIOPSY:
- TWO BENIGN LYMPH NODES (0/2).
- 10) LYMPH NODE, LEFT PARA-AORTIC; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- 11) LYMPH NODES, RIGHT PARA-AORTIC; BIOPSY:
- TWO BENIGN LYMPH NODES (0/2).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file 39af3ad1-b3ab-48a2-bace-54867f9e0f86 (TCGA-AP-A053.6179478F-93BE-4C03-9F65-D74E66AFE449.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).